Somatic mutation profile of tumor specimen 0DDRO6 from CCDI case PBBPEH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 3.3 years (1,217 days).
Specimen 0DDRO6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5be40a1e-14da-4574-98a6-76c56f51c226.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDROD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a5677da-9e39-4a89-8b84-fd47889a91f5

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Nonsense Mutation 2, 3'UTR 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 103/697 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by mutect2, varscan2
- ADAM29 | c.1997C>A p.P666Q | Missense Mutation (SNP) | VAF 20/681 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1481581680, COSV63665258; called by muse, mutect2
- AMTN | c.469G>T p.G157* | Nonsense Mutation (SNP) | VAF 38/582 reads (7%) | catalogued as COSV59490378; called by muse, mutect2
- AOC3 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 40/492 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs139051163; called by muse, mutect2
- PALM2AKAP2 | c.991C>T p.Q331* (on ENST00000259318 / NM_001136562.3; = p.Q562* on NM_007203.5) | Nonsense Mutation (SNP) | VAF 26/368 reads (7%) | catalogued as COSV52182040, COSV52183165; called by muse, mutect2
- PTCHD3 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.741); catalogued as rs768743376, COSV71256692; called by muse, mutect2, varscan2
- SDK1 | c.5050G>A p.G1684S | Missense Mutation (SNP) | VAF 61/729 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs770396523, COSV67379593; called by muse, mutect2
- SHROOM3 | c.5890G>T p.A1964S | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV56038922; called by muse, mutect2
- BTAF1 | c.2881C>T p.H961Y | Missense Mutation (SNP) | VAF 56/558 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2
- CACNA1B | c.6471G>T p.E2157D | Missense Mutation (SNP) | VAF 28/405 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.08); called by muse, mutect2
- CHAF1A | c.2111T>C p.L704P | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DENND1C | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- HLA-DMB | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- IMMP1L | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 86/1024 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MROH5 | c.662G>T p.S221I | Missense Mutation (SNP) | VAF 17/657 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PRKAB2 | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 37/643 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRQ | c.1683G>C p.Q561H (on ENST00000616559; = p.Q519H on NM_001145026.2) | Missense Mutation (SNP) | VAF 61/712 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); called by muse, mutect2
- ADAM21 | c.1674C>A p.V558= | Silent (SNP) | VAF 14/282 reads (5%) | catalogued as COSV99960586; called by muse, mutect2
- IFI16 | c.1764A>T p.S588= (on ENST00000295809 / NM_001364867.2; = p.S532= on NM_005531.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 29/1022 reads (3%) | called by muse, mutect2
- PCDHGA1 | c.1548G>A p.A516= | Silent (SNP) | VAF 31/524 reads (6%) | catalogued as rs752057797; called by muse, mutect2
- RP1L1 | c.1440G>T p.V480= | Silent (SNP) | VAF 11/255 reads (4%) | called by muse, mutect2
- VWDE | c.3561A>G p.G1187= | Silent (SNP) | VAF 50/662 reads (8%) | called by muse, mutect2
- CEP170B | c.*14C>T | 3'UTR (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- GLCCI1 | c.1178-49T>G | Intron (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- KCNC2 | c.-3G>A | 5'UTR (SNP) | VAF 25/689 reads (4%) | called by muse, mutect2
- RTL8A | c.*451G>C | 3'UTR (SNP) | VAF 71/546 reads (13%) | called by muse, mutect2, varscan2
